Somatic mutation profile of tumor specimen TARGET-20-PARBFZ-03A (aliquot TARGET-20-PARBFZ-03A-01D) from TARGET case TARGET-20-PARBFZ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.5 years (5,298 days).
Specimen TARGET-20-PARBFZ-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d621c5c-8c99-440f-8f77-bc8c0415edf2.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARBFZ-14A (Bone Marrow Normal), aliquot TARGET-20-PARBFZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b826d94d-bf56-4bc0-a92f-6ba9be584ddb

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'UTR 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>T p.D816Y | Missense Mutation (SNP) | VAF 90/206 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DOCK3 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs201614726, COSV56547861; called by muse, varscan2
- KMT2D | c.8059_8060insTT p.R2687Lfs*5 | Frame Shift Ins (INS) | VAF 25/65 reads (38%) | called by mutect2, pindel, varscan2
- CUL9 | c.3045G>T p.V1015= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- PPP1R15B | c.-51C>G | 5'UTR (SNP) | VAF 43/107 reads (40%) | catalogued as rs1434244469, COSV100916365; called by muse, mutect2, varscan2
